Somatic mutation profile of cancer-model specimen HCM-BROD-0209-C71-85A (Adherent Cell Line, passage 9; aliquot HCM-BROD-0209-C71-85A-01D-A786-36), derived from the recurrence tumor of HCMI case HCM-BROD-0209-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 41.8 years (15,280 days).
Specimen HCM-BROD-0209-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82c9e65c-c90c-45e6-9d50-7e7b3d611f7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0209-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0209-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e6beb53-8a96-4d0c-954b-42ebb5cd3c3a

The open-access MAF lists 144 somatic variants for this specimen: 93 protein-altering or splice-affecting, 31 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 31, Splice Site 6, 5'UTR 5, Intron 5, Frame Shift Del 4, Nonsense Mutation 3, 5'Flank 3, RNA 3, 3'UTR 3, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIF26B | c.6071G>A p.R2024H | Missense Mutation (SNP) | VAF 79/190 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199933797, COSV63638897; called by muse, mutect2, varscan2
- RB1 | c.1421+1G>C p.X474_splice | Splice Site (SNP) | VAF 56/56 reads (100%) | hotspot (GDC flag); catalogued as rs1131690886, COSV57295416, COSV57303849, COSV57308621; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 200/200 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPRHL1 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 106/201 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs774381207, COSV100733595; called by muse, mutect2, varscan2
- ALDH3B2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 133/266 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs111503561; called by muse, mutect2, varscan2
- BCL11B | c.1217C>T p.T406M (on ENST00000357195 / NM_001282237.2; = p.T335M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1029333696, COSV61733353; called by muse, mutect2, varscan2
- BOD1L1 | c.3649A>G p.N1217D | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV50006332; called by muse, mutect2
- CALR | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 40/929 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as rs139658454, COSV57130781; called by muse, mutect2
- CAPN6 | c.1558A>C p.I520L | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs747889694; called by muse, mutect2, varscan2
- CHAT | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60319565; called by muse, mutect2
- CHRNA9 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 111/217 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs1479555056, COSV59575340; called by muse, mutect2, varscan2
- COL1A1 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 176/354 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs769167761; called by muse, mutect2, varscan2
- CPNE5 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs752953395; called by muse, mutect2, varscan2
- CSMD3 | c.10160G>T p.G3387V (on ENST00000297405 / NM_001363185.1; = p.G3218V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52332998; called by muse, mutect2, varscan2
- DEFB126 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66694832; called by muse, mutect2, varscan2
- DENND5B | c.1993A>G p.T665A | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770983656; called by muse, mutect2, varscan2
- DSP | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 157/299 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144539278, COSV65794417; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 135/213 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99677817; called by muse, mutect2, varscan2
- EPHA3 | c.2819G>C p.C940S | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100347658; called by muse, mutect2, varscan2
- EPPK1 | c.6871G>A p.V2291M | Missense Mutation (SNP) | VAF 48/408 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs1174772692, COSV73260846; called by muse, mutect2, varscan2
- FAM163A | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403683637; called by muse, mutect2, varscan2
- FRMPD4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 128/129 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV101043402; called by muse, mutect2, varscan2
- HHIPL2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV58566285; called by muse, mutect2
- HTT | c.8164G>A p.V2722M | Missense Mutation (SNP) | VAF 60/259 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs753876343; called by muse, mutect2, varscan2
- KCTD18 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs1254636676; called by muse, mutect2, varscan2
- MAP7 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763941595; called by muse, mutect2, varscan2
- MARCHF4 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 188/351 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.763); catalogued as COSV56105119, COSV56108597; called by muse, mutect2, varscan2
- MSH4 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs757262974; called by muse, mutect2, varscan2
- NLRP5 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 200/582 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs199475775, COSV66767095; ClinVar: not provided; called by muse, mutect2, varscan2
- OR51G1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764009160; called by muse, varscan2
- PIEZO2 | c.7016G>A p.R2339H | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99555018; called by muse, varscan2
- POM121L12 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 133/404 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.308); catalogued as COSV68692154; called by muse, mutect2, varscan2
- PRDM7 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs574313407; called by muse, mutect2, varscan2
- PRKCQ | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 184/184 reads (100%) | SIFT tolerated (0.44); PolyPhen benign (0.144); catalogued as rs372791078; called by muse, mutect2, varscan2
- PTEN | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 83/84 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64289312, COSV64292633; called by muse, mutect2, varscan2
- PTPN21 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1209673593, COSV60845575; called by muse, mutect2
- RYR2 | c.11998G>A p.V4000M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773760019; called by muse, mutect2, varscan2
- SCN11A | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs771220857, COSV56565664, COSV56573959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPV6 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63892156; called by muse, mutect2, varscan2
- TUBA3C | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 107/215 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.7); catalogued as rs138384157, COSV68028168; called by muse, mutect2, varscan2
- UNC13A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.249); catalogued as rs566299244, COSV53210618; called by muse, mutect2, varscan2
- YES1 | c.575-1G>T p.X192_splice | Splice Site (SNP) | VAF 47/82 reads (57%) | catalogued as COSV58848418; called by muse, mutect2, varscan2
- ZNF558 | c.885C>G p.H295Q | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100038013; called by muse, mutect2, varscan2
- ZNF716 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1163960650; called by muse, mutect2
- ZNF844 | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 121/333 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as rs746107574; called by muse, mutect2, varscan2
- ABCC12 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ADGRB3 | c.4394C>T p.P1465L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, varscan2
- ADH1B | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ANKRD18B | c.733T>A p.L245M | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.675); called by muse, mutect2
- ASAP3 | c.1618T>C p.F540L | Missense Mutation (SNP) | VAF 138/595 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ATP8A1 | c.2672G>T p.W891L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- CDHR2 | c.1976del p.G659Afs*5 | Frame Shift Del (DEL) | VAF 261/577 reads (45%) | called by mutect2, pindel, varscan2
- CHD7 | c.4645-1G>C p.X1549_splice | Splice Site (SNP) | VAF 86/180 reads (48%) | called by muse, mutect2, varscan2
- DCLK3 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DISP1 | c.3562G>T p.E1188* | Nonsense Mutation (SNP) | VAF 262/594 reads (44%) | called by muse, mutect2, varscan2
- DNAH3 | c.11071+2T>A p.X3691_splice | Splice Site (SNP) | VAF 31/112 reads (28%) | called by muse, varscan2
- DOCK10 | c.1418G>T p.R473I | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ENTPD2 | c.1157C>G p.A386G | Missense Mutation (SNP) | VAF 220/408 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.056); called by muse, mutect2
- GRM5 | c.30A>C p.L10F | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- GSTA4 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 134/269 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- INTS2 | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by mutect2, varscan2
- LAMA2 | c.5942C>T p.A1981V | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MAML1 | c.1292del p.Q431Rfs*10 | Frame Shift Del (DEL) | VAF 54/141 reads (38%) | called by mutect2, pindel, varscan2
- MAP1B | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MBD4 | c.856del p.R286Efs*17 | Frame Shift Del (DEL) | VAF 213/565 reads (38%) | called by mutect2, pindel, varscan2
- MIDEAS | c.3035C>A p.S1012* | Nonsense Mutation (SNP) | VAF 142/308 reads (46%) | called by muse, mutect2, varscan2
- MIPEP | c.2105A>G p.D702G | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MPP3 | c.1458+1G>T p.X486_splice | Splice Site (SNP) | VAF 21/107 reads (20%) | called by muse, mutect2, varscan2
- MYH7B | c.1272T>C p.S424= | Splice Region (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- MYO1D | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.629); called by muse, mutect2
- NFS1 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NHEJ1 | c.896G>C p.S299T | Missense Mutation (SNP) | VAF 198/339 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NR2F6 | c.1183A>G p.T395A | Missense Mutation (SNP) | VAF 86/493 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR10K1 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- OR52K1 | c.889A>G p.K297E | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- OTOGL | c.6267+2T>C p.X2089_splice (on ENST00000547103; = p.X2080_splice on NM_173591.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- PIK3R2 | c.1611G>C p.E537D | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PIWIL1 | c.1559C>A p.P520Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.169); called by muse, mutect2
- PLXND1 | c.2531T>C p.V844A | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PNPLA6 | c.3515A>G p.D1172G (on ENST00000414982 / NM_001166111.2; = p.D1124G on NM_006702.5) | Missense Mutation (SNP) | VAF 129/590 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPP1R15B | c.445T>A p.W149R | Missense Mutation (SNP) | VAF 96/171 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- RAB40B | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 110/521 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RPF2 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SDK1 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 129/375 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- SLC22A15 | c.1178G>C p.G393A | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPEN | c.1132T>C p.Y378H | Missense Mutation (SNP) | VAF 58/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCAF2C | c.1618A>C p.M540L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.087); called by mutect2, varscan2
- TNNI3 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- UHMK1 | c.1005del p.N336Mfs*9 (on ENST00000489294 / NM_175866.5; = p.N336Mfs*55 on NM_144624.2) | Frame Shift Del (DEL) | VAF 69/194 reads (36%) | called by mutect2, pindel, varscan2
- XCL2 | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB11 | c.2137G>T p.V713F | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); called by muse, mutect2
- ZNF354B | c.1684A>T p.S562C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ZNF667 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- ABRA | c.648C>T p.I216= | Silent (SNP) | VAF 34/141 reads (24%) | called by muse, mutect2, varscan2
- BRSK1 | c.981C>A p.G327= | Silent (SNP) | VAF 17/474 reads (4%) | called by muse, mutect2
- CNTNAP4 | c.1680C>T p.H560= | Silent (SNP) | VAF 89/130 reads (68%) | catalogued as rs779366718; called by muse, mutect2, varscan2
- DHX37 | c.1302C>T p.S434= | Silent (SNP) | VAF 84/227 reads (37%) | catalogued as rs950622312; called by muse, mutect2, varscan2
- DNAH6 | c.6156A>T p.R2052= | Silent (SNP) | VAF 132/265 reads (50%) | called by muse, mutect2, varscan2
- DRC1 | c.1950G>A p.K650= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- EGF | c.192C>A p.T64= | Silent (SNP) | VAF 110/226 reads (49%) | catalogued as rs367667834; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHA4 | c.75A>G p.V25= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as rs1222084743; called by muse, mutect2, varscan2
- FMN1 | c.1539A>G p.T513= | Silent (SNP) | VAF 157/345 reads (46%) | catalogued as rs771538811; called by muse, mutect2, varscan2
- HNRNPH1 | c.207G>A p.L69= | Silent (SNP) | VAF 39/187 reads (21%) | called by muse, mutect2, varscan2
- HOXA2 | c.99A>G p.Q33= | Silent (SNP) | VAF 144/855 reads (17%) | called by muse, mutect2, varscan2
- HRNR | c.6594C>T p.H2198= | Silent (SNP) | VAF 222/1739 reads (13%) | catalogued as rs534099891, COSV64254199; called by mutect2, varscan2
- HTR3A | c.1260G>A p.Q420= | Silent (SNP) | VAF 19/607 reads (3%) | catalogued as COSV55467980; called by muse, mutect2
- ITGA4 | c.1278G>A p.S426= | Silent (SNP) | VAF 41/107 reads (38%) | catalogued as rs201581651, COSV52001707, COSV99275884; called by muse, mutect2, varscan2
- KLK3 | c.303C>T p.Y101= | Silent (SNP) | VAF 61/478 reads (13%) | catalogued as rs374344392; called by muse, mutect2, varscan2
- LINGO2 | c.837C>T p.N279= | Silent (SNP) | VAF 129/258 reads (50%) | called by muse, mutect2, varscan2
- LRP1B | c.4965A>G p.A1655= | Silent (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- LUC7L2 | c.318A>G p.K106= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- MAP7D3 | c.1485T>C p.Y495= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs1247168632; called by muse, mutect2, varscan2
- MAVS | c.744A>G p.V248= | Silent (SNP) | VAF 94/399 reads (24%) | catalogued as rs752018252; called by muse, mutect2, varscan2
- NEURL1 | c.753C>T p.S251= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- PHF3 | c.915T>C p.G305= | Silent (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- PPFIA1 | c.2031A>T p.S677= | Silent (SNP) | VAF 15/422 reads (4%) | called by muse, mutect2
- RELL2 | c.264C>T p.A88= | Silent (SNP) | VAF 94/174 reads (54%) | called by muse, mutect2, varscan2
- SCN5A | c.141C>T p.P47= | Silent (SNP) | VAF 182/358 reads (51%) | catalogued as rs571894716; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAT6 | c.525A>T p.P175= | Silent (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- TMEM88B | c.285C>T p.C95= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.135T>C p.C45= | Silent (SNP) | VAF 73/456 reads (16%) | called by muse, mutect2, varscan2
- UCP3 | c.501A>G p.R167= | Silent (SNP) | VAF 162/612 reads (26%) | catalogued as rs1465760527; called by muse, mutect2, varscan2
- VSIG10L | c.912G>T p.L304= | Silent (SNP) | VAF 28/216 reads (13%) | called by mutect2, varscan2
- ZNF335 | c.3342T>C p.R1114= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- ALB | c.-13C>T | 5'UTR (SNP) | VAF 70/178 reads (39%) | catalogued as rs369763404; called by muse, mutect2, varscan2
- BET1 | c.-31C>A | 5'UTR (SNP) | VAF 19/370 reads (5%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+38522C>G | Intron (SNP) | VAF 107/226 reads (47%) | called by muse, mutect2, varscan2
- C11orf40 | n.397C>T | RNA (SNP) | VAF 84/133 reads (63%) | catalogued as rs772223493; called by muse, mutect2, varscan2
- CACNB2 | c.120+260A>G | Intron (SNP) | VAF 79/165 reads (48%) | catalogued as rs1056769153; called by muse, mutect2, varscan2
- CR1 | c.487+11993G>A | Intron (SNP) | VAF 233/526 reads (44%) | called by muse, mutect2, varscan2
- GLTPP1 | chr11:18188945 C>T | 5'Flank (SNP) | VAF 117/370 reads (32%) | catalogued as rs1380117276; called by muse, mutect2, varscan2
- HERC2P3 | n.1119G>A | RNA (SNP) | VAF 246/759 reads (32%) | catalogued as rs753822098; called by muse, mutect2, varscan2
- HOOK1 | c.-40_-37delinsGTT | 5'UTR (DEL) | VAF 61/288 reads (21%) | called by mutect2*, pindel, varscan2*
- KLHL7 | c.121-5823T>C | Intron (SNP) | VAF 57/340 reads (17%) | catalogued as COSV59161002; called by muse, mutect2, varscan2
- KMO | chr1:241532356 A>G | 5'Flank (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- PABPC1P2 | n.690G>T | RNA (SNP) | VAF 109/226 reads (48%) | catalogued as rs753648140; called by muse, mutect2, varscan2
- PLEKHM1 | c.*983G>A | 3'UTR (SNP) | VAF 102/188 reads (54%) | called by muse, mutect2, varscan2
- RALGDS | c.*41T>G | 3'UTR (SNP) | VAF 163/344 reads (47%) | catalogued as rs772780500; called by muse, mutect2, varscan2
- RNU6-389P | chr7:55687839 C>T | 3'Flank (SNP) | VAF 113/489 reads (23%) | catalogued as rs757960757; called by muse, mutect2, varscan2
- SLC25A40 | c.*49A>G | 3'UTR (SNP) | VAF 35/233 reads (15%) | called by muse, mutect2, varscan2
- SOHLH1 | c.-29G>A | 5'UTR (SNP) | VAF 224/441 reads (51%) | catalogued as rs745716133; called by muse, mutect2, varscan2
- TESC | c.-127G>A | 5'UTR (SNP) | VAF 44/63 reads (70%) | called by muse, mutect2, varscan2
- TTC6 | chr14:37792327 G>A | 5'Flank (SNP) | VAF 55/55 reads (100%) | catalogued as rs556874303; called by muse, mutect2, varscan2
- ZEB2 | c.73+4999T>G | Intron (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
